Somatic mutation profile of tumor specimen TCGA-24-2280-01A (aliquot TCGA-24-2280-01A-01W-0799-08) from TCGA case TCGA-24-2280, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.9 years (27,356 days).
Specimen TCGA-24-2280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 272c2b19-5e55-4c7c-a197-f83cae502d11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2280-10A (Blood Derived Normal), aliquot TCGA-24-2280-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/896dbb9b-ae00-4ba3-a3c0-40ed61fafc77

The open-access MAF lists 201 somatic variants for this specimen: 150 protein-altering or splice-affecting, 46 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 46, Nonsense Mutation 12, Frame Shift Del 4, Intron 3, In Frame Del 2, 3'UTR 1, In Frame Ins 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPYD | c.232A>T p.R78* | Nonsense Mutation (SNP) | VAF 28/138 reads (20%) | catalogued as rs776692894, COSV60080726; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 58/130 reads (45%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACADSB | c.464C>G p.T155R | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs769921991, COSV62551061; called by muse, mutect2, varscan2
- ADGRB3 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV65405462; called by muse, mutect2, varscan2
- AFF4 | c.2894C>T p.S965F | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54792357, COSV99534808; called by muse, mutect2, varscan2
- AGFG1 | c.356A>G p.E119G | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100028897; called by muse, mutect2
- AHNAK | c.10723C>T p.P3575S | Missense Mutation (SNP) | VAF 83/284 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV57208583; called by muse, mutect2, varscan2
- AHSG | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 56/653 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV99890111; called by muse, mutect2
- AIG1 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51629547; called by muse, mutect2, varscan2
- ANGPTL1 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99328224; called by muse, mutect2
- ANKRD35 | c.2738A>T p.K913I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV62910922; called by muse, mutect2, varscan2
- ARAP3 | c.1474G>C p.A492P | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99499842; called by muse, mutect2
- ARHGAP32 | c.3070G>T p.V1024F (on ENST00000310343 / NM_001378025.1; = p.V675F on NM_014715.4) | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV59851226; called by muse, mutect2, varscan2
- ASAP2 | c.2459C>A p.S820Y | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55633972, COSV99856343; called by muse, mutect2
- ASB2 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60113163; called by muse, mutect2, varscan2
- ASIC2 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs753583147, COSV63301407; called by muse, mutect2, varscan2
- AVPR1B | c.488T>A p.I163N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV65638335; called by muse, mutect2, varscan2
- BMP7 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 47/530 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101216039; called by muse, mutect2
- BRINP1 | c.1284C>A p.C428* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV56292447, COSV99774759, COSV99775887; called by mutect2, varscan2
- C2orf78 | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101280990; called by muse, mutect2, varscan2
- C5orf34 | c.260C>G p.T87S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60931058; called by muse, mutect2, varscan2
- CACNA1G | c.4754C>G p.A1585G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61731674; called by muse, mutect2
- CATSPERD | c.1865C>G p.A622G | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58466114; called by muse, mutect2, varscan2
- CHRNA3 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 33/696 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100468370; called by muse, mutect2
- CNGB1 | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 25/208 reads (12%) | catalogued as COSV51903271; called by muse, mutect2, varscan2
- CNTFR | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376033873; called by muse, mutect2, varscan2
- CNTN6 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 22/688 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100610943; called by muse, mutect2
- COL4A6 | c.1763G>C p.G588A | Missense Mutation (SNP) | VAF 19/347 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100564333; called by muse, mutect2
- COL5A3 | c.3569G>T p.G1190V | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53414256; called by muse, mutect2, varscan2
- CPA5 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 90/292 reads (31%) | catalogued as COSV62570123; called by muse, mutect2, varscan2
- CPT1A | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV55758445, COSV55762165; called by muse, mutect2, varscan2
- CRTAM | c.531T>A p.C177* | Nonsense Mutation (SNP) | VAF 40/180 reads (22%) | catalogued as COSV57066275, COSV57069359; called by muse, mutect2, varscan2
- CS | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1271918641, COSV57525343; called by muse, mutect2, varscan2
- DGKA | c.1802A>C p.N601T | Missense Mutation (SNP) | VAF 66/722 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59387107; called by muse, mutect2
- DNAH1 | c.5957T>C p.M1986T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV70231781; called by muse, mutect2, varscan2
- DNAH5 | c.1490A>C p.Q497P | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs769654757, COSV54217296, COSV99450822; called by muse, mutect2
- DNAH7 | c.10370A>T p.K3457I | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56773470; called by muse, mutect2, varscan2
- DSCAML1 | c.6275C>T p.T2092I (on ENST00000321322; = p.T2032I on NM_020693.4) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as COSV58396119; called by muse, mutect2, varscan2
- DSG1 | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57137133; called by muse, mutect2, varscan2
- DYNC2H1 | c.3792A>T p.L1264F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as rs762546542, COSV62099281; called by muse, mutect2
- EIF4G3 | c.3496C>G p.Q1166E | Missense Mutation (SNP) | VAF 59/445 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.428); catalogued as COSV51687053; called by muse, mutect2, varscan2
- EOMES | c.2037T>G p.Y679* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | catalogued as COSV55413460; called by muse, mutect2, varscan2
- EPB41 | c.2374T>C p.S792P (on ENST00000343067 / NM_001166005.2; = p.S583P on NM_203342.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV58050203; called by muse, mutect2, varscan2
- EPS8L3 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs930153837, COSV62609914; called by muse, mutect2, varscan2
- EXOC6 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs773470955, COSV53327861; called by muse, mutect2, varscan2
- FAT3 | c.3759G>T p.Q1253H | Missense Mutation (SNP) | VAF 241/1498 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.878); catalogued as COSV53107270, COSV53138707; called by muse, mutect2, varscan2
- FGA | c.1622T>A p.V541D | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as CD149607, CD972214, COSV57397977; called by muse, mutect2, varscan2
- FLG2 | c.1716G>C p.L572F | Missense Mutation (SNP) | VAF 112/781 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV66170398; called by muse, mutect2, varscan2
- FMN1 | c.3997C>T p.R1333* (on ENST00000616417 / NM_001277313.2; = p.R1110* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 15/156 reads (10%) | catalogued as rs1189166915, COSV57917773; called by muse, mutect2, varscan2
- GHR | c.1169G>C p.C390S | Missense Mutation (SNP) | VAF 207/520 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs949031881, COSV50119144; called by muse, mutect2, varscan2
- GLI2 | c.1257G>T p.E419D (on ENST00000361492 / NM_001374353.1; = p.E436D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100083438; called by muse, mutect2
- GPR161 | c.113C>G p.T38S | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54792120; called by muse, mutect2
- GPRC5A | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 286/1878 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV50008107; called by muse, mutect2, varscan2
- GRIN2D | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV54380504; called by muse, varscan2
- H1-1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55119224; called by muse, mutect2, varscan2
- HPCA | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65103122; called by muse, mutect2, varscan2
- IGSF3 | c.3106G>A p.V1036M (on ENST00000369486 / NM_001007237.3; = p.V1056M on NM_001542.4) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as rs778484193, COSV59591088; called by muse, mutect2, varscan2
- IK | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.935); catalogued as COSV52801975; called by muse, mutect2, varscan2
- INSR | c.3281C>A p.S1094Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57166590; called by muse, mutect2, varscan2
- KCNH1 | c.2354C>A p.A785D (on ENST00000271751 / NM_172362.3; = p.A758D on NM_002238.4) | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as COSV55076424; called by muse, mutect2
- KCNH8 | c.496C>G p.R166G | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV60469245, COSV60476143; called by muse, mutect2, varscan2
- KDR | c.1847T>A p.M616K | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV55764971, COSV55772365, COSV99817974; called by muse, mutect2
- KIF3A | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.643); catalogued as COSV66415360, COSV66415450; called by muse, mutect2, varscan2
- KIR3DL3 | c.978T>G p.I326M | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52549405; called by muse, mutect2, varscan2
- LINGO2 | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 90/664 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.223); catalogued as rs778495456, COSV58061548; called by muse, mutect2, varscan2
- LMO7 | c.1170G>T p.K390N (on ENST00000357063; = p.K120N on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/1114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100413407; called by muse, mutect2
- LRIG2 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV100743445; called by muse, mutect2
- LRRC7 | c.2649G>C p.W883C (on ENST00000651989 / NM_001370785.2; = p.W850C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50434938, COSV99227651; called by muse, mutect2, varscan2
- MCMDC2 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV58037741; called by muse, mutect2, varscan2
- MMP27 | c.891del p.F298Lfs*20 | Frame Shift Del (DEL) | VAF 32/178 reads (18%) | catalogued as rs1565426428; called by mutect2, pindel, varscan2
- MRC1 | c.1480G>A p.G494S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as rs913798931, COSV53469900; called by muse, mutect2, varscan2
- MTERF3 | c.977A>T p.N326I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1316140187, COSV54633462; called by muse, mutect2, varscan2
- MYBPHL | c.371A>C p.Q124P | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV64062745; called by muse, mutect2, varscan2
- NDUFAF7 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV50016891; called by muse, mutect2, varscan2
- NLRP8 | c.370A>C p.I124L | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV52590257; called by muse, mutect2, varscan2
- NOMO1 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 141/733 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV55059821, COSV55061913; called by muse, mutect2, varscan2
- NPAP1 | c.1868C>A p.P623Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.087); catalogued as COSV61508744; called by muse, mutect2, varscan2
- NRF1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV99781876; called by muse, mutect2
- NTRK1 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs1023556915, COSV62323976; called by muse, mutect2, varscan2
- NTRK1 | c.1611C>A p.D537E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.279); catalogued as COSV62326795; called by muse, mutect2, varscan2
- NUAK2 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV100904091; called by muse, mutect2
- OLIG3 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.292); catalogued as COSV62988826; called by muse, mutect2
- OMD | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV65020329; called by muse, mutect2
- OR12D3 | c.255C>G p.C85W | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101011327; called by muse, mutect2
- OR1S2 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 48/504 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs138124206, COSV56919939; called by muse, mutect2
- OR52N5 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 41/88 reads (47%) | catalogued as rs1341893088, COSV57698878, COSV57699126; called by muse, mutect2, varscan2
- OR6A2 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV60265353; called by muse, mutect2, varscan2
- PAPSS2 | c.1274C>G p.T425S | Missense Mutation (SNP) | VAF 116/264 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV63264145; called by muse, varscan2
- PAX3 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 213/478 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100399789; called by muse, mutect2, varscan2
- PDE11A | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs755213594, COSV53700245, COSV99612405; called by muse, mutect2, varscan2
- PDGFRA | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV57270531; called by muse, mutect2, varscan2
- PFN2 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 105/411 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53524322; called by muse, mutect2, varscan2
- PHLPP2 | c.695C>A p.T232N | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as rs1452071941, COSV100673733; called by muse, mutect2
- PI4KB | c.1373C>A p.A458D (on ENST00000368873 / NM_001369623.1; = p.A470D on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV99649857; called by muse, mutect2
- PKP4 | c.1325T>C p.L442S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV67678125; called by muse, mutect2, varscan2
- PPM1E | c.1568G>T p.G523V | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57576610; called by muse, mutect2, varscan2
- PPM1H | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99956005; called by muse, mutect2
- PRDM1 | c.1202C>A p.A401D | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); catalogued as COSV100958849; called by muse, mutect2, varscan2
- PRR23B | c.420A>T p.E140D | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.89); catalogued as COSV100272114, COSV61493153; called by muse, mutect2
- PTPRD | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs765439647, COSV61961220; called by muse, mutect2, varscan2
- PTPRS | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV53626958; called by muse, mutect2, varscan2
- RAB11FIP1 | c.568T>A p.S190T | Missense Mutation (SNP) | VAF 71/462 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54761746; called by muse, mutect2, varscan2
- RAPGEF2 | c.2768C>T p.T923I | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.096); catalogued as COSV52430497; called by muse, mutect2, varscan2
- RASGRF1 | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV67250545; called by muse, mutect2, varscan2
- RICTOR | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99705180; called by muse, mutect2, varscan2
- RNASE13 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV58795163; called by muse, mutect2, varscan2
- RNF133 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 69/453 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs773033412, COSV57360400, COSV57372554; called by muse, mutect2, varscan2
- RNF182 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV101337916; called by muse, mutect2
- RPRD2 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 45/418 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV100954730; called by muse, mutect2, varscan2
- SAGE1 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.373); catalogued as rs782116354, COSV61013660; called by muse, mutect2, varscan2
- SCAF1 | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV62182802; called by muse, varscan2
- SDK1 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as COSV67377943, COSV67381126; called by muse, mutect2, varscan2
- SEC14L1 | c.314G>C p.R105P | Missense Mutation (SNP) | VAF 78/893 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101171072; called by muse, mutect2
- SERPINA7 | c.245T>A p.F82Y | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV100568482, COSV59666468; called by muse, mutect2, varscan2
- SEZ6 | c.2218C>A p.P740T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57982436; called by muse, mutect2, varscan2
- SH3GL3 | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs766883664, COSV61057192; called by muse, mutect2, varscan2
- SIRT1 | c.2080G>C p.E694Q | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99281862; called by muse, mutect2
- SLC17A1 | c.996C>A p.S332R | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs757219937, COSV55080188, COSV99765946; called by muse, mutect2, varscan2
- SLC2A14 | c.1351T>G p.L451V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV61587320; called by mutect2, varscan2
- SLC35B2 | c.1288C>A p.Q430K | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV51487566, COSV99241186; called by muse, mutect2
- SLIT1 | c.1483A>T p.I495F | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV56593160; called by muse, mutect2, varscan2
- SMAD4 | c.32C>A p.T11K | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100747938; called by muse, mutect2, varscan2
- SOCS2 | c.215T>A p.I72N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61392363; called by muse, mutect2, varscan2
- SRCAP | c.6096C>G p.F2032L | Missense Mutation (SNP) | VAF 108/429 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV52676115, COSV99351722; called by muse, mutect2, varscan2
- SSUH2 | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as rs1029989098, COSV58031497; called by muse, mutect2, varscan2
- TACC3 | c.2075A>G p.K692R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100508794; called by muse, mutect2
- TCERG1 | c.2962C>G p.P988A | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57039035; called by muse, mutect2, varscan2
- TECTA | c.5480G>C p.R1827T | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.997); catalogued as COSV50741702; called by muse, mutect2, varscan2
- TIE1 | c.3121G>T p.V1041F | Missense Mutation (SNP) | VAF 339/605 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65250343; called by muse, mutect2, varscan2
- TINAG | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99449854; called by muse, mutect2
- TRIT1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 148/327 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV57549066; called by muse, mutect2, varscan2
- UGT1A5 | c.257A>C p.Q86P | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV59392705; called by muse, mutect2, varscan2
- ULK2 | c.1581G>T p.Q527H | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.896); catalogued as COSV64446736; called by muse, mutect2, varscan2
- UNC13C | c.1789C>A p.L597M | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs773014396, COSV52895240; called by muse, mutect2, varscan2
- VPS13C | c.9050C>A p.T3017N (on ENST00000644861 / NM_020821.3; = p.T2974N on NM_017684.5) | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as COSV51297222; called by muse, mutect2, varscan2
- WDR6 | c.1232C>G p.A411G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100556506; called by muse, mutect2
- XRCC2 | c.337G>C p.G113R | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV100831652, COSV63770033; called by muse, mutect2
- YWHAG | c.289T>A p.C97S | Missense Mutation (SNP) | VAF 90/974 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100297374; called by muse, mutect2
- ZBTB25 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776514676, COSV67198504; called by muse, mutect2, varscan2
- ZDHHC12 | c.65G>A p.W22* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as rs867705969, COSV52577992; called by muse, mutect2, varscan2
- ZNF831 | c.4585C>A p.P1529T | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as COSV64042397; called by muse, mutect2, varscan2
- ATL3 | c.179_182dup p.V62Gfs*38 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- BEST3 | c.638_660del p.E213Vfs*8 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel
- CCDC87 | c.2048_2066del p.H683Lfs*13 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- DEPTOR | c.78_79insATGGGGAAGGGTTTG p.E26_L27insMGKGL | In Frame Ins (INS) | VAF 5/42 reads (12%) | called by mutect2, pindel*
- GAPVD1 | c.961_979del p.N321* | Frame Shift Del (DEL) | VAF 40/240 reads (17%) | called by mutect2, pindel, varscan2
- MPND | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SERPINC1 | c.704_718del p.P235_N240delinsH | In Frame Del (DEL) | VAF 27/346 reads (8%) | called by mutect2, pindel*
- TAF15 | c.833A>T p.D278V (on ENST00000605844 / NM_139215.3; = p.D275V on NM_003487.4) | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- XPOT | c.2044_2064del p.D682_L688del | In Frame Del (DEL) | VAF 38/393 reads (10%) | called by mutect2, pindel
- AC011448.1 | c.36G>C p.P12= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs11552886, COSV53064380; called by muse, mutect2, varscan2
- ADD2 | c.573G>A p.L191= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV52460359; called by muse, mutect2, varscan2
- ARHGEF4 | c.1578C>T p.H526= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV58125245; called by muse, mutect2, varscan2
- CAMTA1 | c.3405G>T p.R1135= | Silent (SNP) | VAF 15/395 reads (4%) | catalogued as COSV100350632; called by muse, mutect2
- CELF5 | c.957T>C p.N319= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99485994; called by muse, mutect2
- CIBAR2 | c.489G>T p.L163= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV73320548; called by muse, mutect2, varscan2
- CNTNAP2 | c.1761G>C p.G587= | Silent (SNP) | VAF 74/329 reads (22%) | catalogued as COSV100667289; called by muse, mutect2, varscan2
- CYP20A1 | c.792A>G p.Q264= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV61909872; called by muse, mutect2, varscan2
- DMP1 | c.336C>T p.D112= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV56820845, COSV99218982; called by muse, mutect2, varscan2
- DSP | c.2967T>C p.S989= | Silent (SNP) | VAF 90/186 reads (48%) | catalogued as rs1338136683, COSV65793864; called by muse, mutect2, varscan2
- EBF3 | c.672C>T p.H224= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs371268793; called by muse, mutect2, varscan2
- FAM135B | c.4206C>A p.L1402= | Silent (SNP) | VAF 42/319 reads (13%) | catalogued as COSV52736745, COSV52737679; called by muse, mutect2, varscan2
- FBN1 | c.7839C>T p.S2613= | Silent (SNP) | VAF 61/419 reads (15%) | catalogued as rs193922238, COSV57322688; ClinVar: likely benign; called by muse, mutect2, varscan2
- FCRL5 | c.1341C>T p.Y447= | Silent (SNP) | VAF 159/446 reads (36%) | catalogued as rs765623333, COSV62516955; called by muse, mutect2, varscan2
- GALNT1 | c.75G>A p.L25= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV52453445; called by muse, mutect2, varscan2
- GRIN2D | c.2160G>A p.K720= | Silent (SNP) | VAF 103/277 reads (37%) | catalogued as rs1324638566, COSV54380494; called by muse, varscan2
- GYS1 | c.1047C>G p.L349= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as COSV54403872; called by muse, mutect2
- HOXC9 | c.729A>G p.R243= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV57716927; called by muse, mutect2, varscan2
- HYPK | c.76C>A p.R26= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs1271198735, COSV51039652; called by muse, mutect2, varscan2
- IL21R | c.729G>T p.L243= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV100560207; called by muse, mutect2, varscan2
- KRTAP20-2 | c.171A>T p.G57= | Silent (SNP) | VAF 85/586 reads (15%) | catalogued as COSV58183527; called by muse, mutect2, varscan2
- MBL2 | c.294A>T p.G98= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV100906353; called by muse, mutect2
- MLIP | c.1254C>T p.S418= | Silent (SNP) | VAF 268/1058 reads (25%) | catalogued as COSV51432828; called by muse, varscan2
- NSD2 | c.1017G>A p.E339= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as rs375995389; called by muse, mutect2, varscan2
- NUP210L | c.3540A>G p.A1180= | Silent (SNP) | VAF 106/250 reads (42%) | catalogued as COSV99668305; called by muse, mutect2, varscan2
- OR4C46 | c.675T>A p.T225= | Silent (SNP) | VAF 61/203 reads (30%) | catalogued as COSV60220280; called by muse, mutect2, varscan2
- OR6Q1 | c.327C>A p.T109= | Silent (SNP) | VAF 50/556 reads (9%) | catalogued as COSV56933694; called by muse, mutect2
- OSBPL3 | c.1146C>T p.N382= | Silent (SNP) | VAF 24/436 reads (6%) | catalogued as rs767974595, COSV57652142; called by muse, mutect2
- PCDHA4 | c.1305G>A p.L435= | Silent (SNP) | VAF 202/266 reads (76%) | catalogued as rs1448615626, COSV63543467; called by muse, mutect2, varscan2
- PHLDB2 | c.2784C>A p.P928= (on ENST00000393925 / NM_001134439.2; = p.P885= on NM_145753.2) | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV67313379; called by muse, mutect2, varscan2
- PLCZ1 | c.720T>A p.S240= | Silent (SNP) | VAF 13/276 reads (5%) | catalogued as COSV56848854; called by muse, mutect2
- POLG2 | c.1083T>C p.F361= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as COSV101604426; called by muse, mutect2
- PRDM15 | c.1743A>G p.R581= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as COSV54155639; called by muse, mutect2, varscan2
- PRRC2A | c.2943A>G p.P981= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV101051222; called by muse, mutect2
- PRSS36 | c.942G>A p.R314= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV51636206; called by muse, mutect2, varscan2
- QARS1 | c.1731C>A p.V577= | Silent (SNP) | VAF 17/241 reads (7%) | catalogued as COSV100070101; called by muse, mutect2
- SEC14L1 | c.315G>C p.R105= | Silent (SNP) | VAF 78/908 reads (9%) | catalogued as COSV101171075; called by muse, mutect2
- SMPD1 | c.1800T>G p.S600= | Silent (SNP) | VAF 46/167 reads (28%) | catalogued as COSV54969037; called by muse, mutect2, varscan2
- SPATA31D1 | c.1926G>T p.V642= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV61198184; called by muse, mutect2, varscan2
- TGIF2 | c.540C>T p.F180= | Silent (SNP) | VAF 49/317 reads (15%) | catalogued as COSV65836675; called by muse, mutect2, varscan2
- TMEM168 | c.864T>A p.T288= | Silent (SNP) | VAF 44/379 reads (12%) | catalogued as COSV100454655; called by muse, mutect2, varscan2
- VLDLR | c.1353C>T p.I451= | Silent (SNP) | VAF 90/568 reads (16%) | catalogued as COSV66074214; called by muse, mutect2, varscan2
- YWHAG | c.288G>A p.V96= | Silent (SNP) | VAF 90/978 reads (9%) | catalogued as COSV100297375; called by muse, mutect2
- ZNF266 | c.159T>G p.L53= | Silent (SNP) | VAF 41/827 reads (5%) | catalogued as COSV100749404; called by muse, mutect2
- ZNF546 | c.234C>T p.D78= | Silent (SNP) | VAF 96/464 reads (21%) | catalogued as rs760436332, COSV61258452; called by muse, mutect2, varscan2
- ZNF572 | c.1017T>C p.R339= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as rs778286370, COSV60001839; called by muse, mutect2, varscan2
- CADPS | c.2582-889A>C | Intron (SNP) | VAF 15/82 reads (18%) | catalogued as COSV51889564; called by muse, mutect2, varscan2
- DNM2 | c.1336-1091C>A | Intron (SNP) | VAF 20/44 reads (45%) | catalogued as COSV58966214; called by muse, mutect2, varscan2
- H2AC17 | c.*2G>T | 3'UTR (SNP) | VAF 12/362 reads (3%) | called by muse, mutect2
- NCF4 | c.758+41C>A | Intron (SNP) | VAF 90/843 reads (11%) | catalogued as COSV50624050; called by muse, mutect2, varscan2
- OR52A4P | chr11:5121142 G>T | 3'Flank (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
